Somatic mutation profile of tumor specimen TCGA-CM-5348-01A (aliquot TCGA-CM-5348-01A-21D-1719-10) from TCGA case TCGA-CM-5348, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.7 years (26,543 days).
Specimen TCGA-CM-5348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 023cf934-f4d8-4e2b-a5ac-9930525adc32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5348-10A (Blood Derived Normal), aliquot TCGA-CM-5348-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e208a77-8106-446c-831c-400f095b46f6

The open-access MAF lists 193 somatic variants for this specimen: 142 protein-altering or splice-affecting, 50 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 50, Nonsense Mutation 8, Frame Shift Del 5, Splice Site 3, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 88/180 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs145086947, COSV55118101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTA1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64203934; called by muse, mutect2
- ADAMTS14 | c.2146G>C p.V716L | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV64599759; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 151/279 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs766069046, COSV57860124; called by muse, mutect2, varscan2
- ADGRB2 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.434); catalogued as rs774818699, COSV57070793; called by muse, mutect2, varscan2
- AKAP11 | c.2477G>C p.R826T | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs376563786, COSV50296573; called by muse, mutect2, varscan2
- AKT3 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55606407, COSV55608251; called by muse, mutect2, varscan2
- ALDH1L2 | c.1138A>C p.R380= | Splice Region (SNP) | VAF 10/61 reads (16%) | catalogued as COSV51553207; called by muse, mutect2, varscan2
- ANK1 | c.4870G>A p.D1624N | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.311); catalogued as rs768806998, COSV99224215; called by muse, mutect2, varscan2
- APBA2 | c.2084G>T p.R695L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68788597, COSV68788915; called by muse, mutect2, varscan2
- APOB | c.6510A>C p.K2170N | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV99263991; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747805882, COSV63437124; called by muse, mutect2, varscan2
- ATAD5 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100429711; called by muse, mutect2
- C11orf49 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as rs762721628, COSV53563337; called by muse, mutect2, varscan2
- C8orf76 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 380/711 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52689907; called by muse, mutect2, varscan2
- CA8 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1272473136, COSV58770477; called by muse, mutect2, varscan2
- CACNA2D3 | c.3103-2A>G p.X1035_splice (on ENST00000288197; = p.Y1034C on NM_018398.3) | Splice Site (SNP) | VAF 43/121 reads (36%) | catalogued as rs550918018, COSV55516280, COSV55522197; called by muse, mutect2, varscan2
- CAMK1D | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66607067; called by muse, mutect2
- CAVIN2 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs767172526, COSV58424792, COSV58426105; called by muse, mutect2, varscan2
- CCDC172 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs187810520, COSV60936682; called by muse, mutect2, varscan2
- CCNB3 | c.2774T>C p.V925A | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52070078; called by muse, mutect2, varscan2
- CD40 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64847516; called by muse, mutect2, varscan2
- CEND1 | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs759288352, COSV100204115, COSV57192722; called by muse, mutect2, varscan2
- CEP78 | c.1178G>A p.R393H (on ENST00000424347 / NM_001349840.2; = p.R394H on NM_032171.3) | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018373694, COSV52845535; called by muse, mutect2, varscan2
- CHST6 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100178289; called by muse, mutect2, varscan2
- CLTCL1 | c.4448C>G p.S1483C | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54225498; called by muse, mutect2
- CTCFL | c.503A>T p.K168M | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs767256851, COSV99712209; called by muse, varscan2
- CTNNBL1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs764634448, COSV100799356, COSV63745348; called by muse, mutect2, varscan2
- CUEDC1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV64226057; called by muse, mutect2, varscan2
- DAPP1 | c.99G>A p.L33= | Splice Region (SNP) | VAF 32/59 reads (54%) | catalogued as COSV56449841, COSV56452804; called by muse, mutect2, varscan2
- DBF4B | c.1804C>G p.Q602E | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV100154321; called by muse, mutect2, varscan2
- DCT | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375600704; called by muse, mutect2, varscan2
- DDX60 | c.4219G>T p.D1407Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV101190290; called by muse, mutect2
- DISP3 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); catalogued as rs759615246, COSV53821020; called by muse, mutect2, varscan2
- DNAH5 | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99445859; called by muse, mutect2, varscan2
- DOC2A | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as rs373250621, COSV58750952; called by muse, mutect2, varscan2
- DRC3 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 88/158 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377575498; called by muse, mutect2, varscan2
- DSCAM | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs755881168, COSV68024346; called by muse, mutect2, varscan2
- DYNC1I1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 181/595 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV61456086; called by muse, mutect2, varscan2
- EDC4 | c.2131C>A p.L711M | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV59301968; called by muse, mutect2
- EDNRA | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 248/474 reads (52%) | catalogued as COSV60095771; called by muse, mutect2, varscan2
- EDNRB | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1246433594, COSV57519112; called by muse, mutect2, varscan2
- EPS8 | c.2264T>C p.L755P | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99842724; called by muse, mutect2, varscan2
- ERC2 | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55602336; called by muse, mutect2, varscan2
- EXT1 | c.1896C>A p.Y632* | Nonsense Mutation (SNP) | VAF 50/275 reads (18%) | catalogued as CM065159, CM092513, COSV65475292; called by muse, mutect2, varscan2
- FAM120B | c.2693-1G>A p.X898_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as COSV53001461, COSV99380009; called by muse, mutect2, varscan2
- FAM155B | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as COSV52935261; called by muse, mutect2, varscan2
- FAM181A | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as rs745432413, COSV50887844; called by muse, mutect2, varscan2
- FASTKD1 | c.1187T>A p.F396Y | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV71624103; called by muse, mutect2, varscan2
- FUBP1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV53926717, COSV53935726; called by muse, mutect2, varscan2
- GCNA | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 371/556 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65465932; called by muse, mutect2, varscan2
- GPR137 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs761684438, COSV100464042; called by muse, mutect2, varscan2
- GPR15 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs746880733, COSV52520058; called by muse, mutect2, varscan2
- GRIA4 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752319424, COSV56883011; called by muse, mutect2, varscan2
- GRID1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs768009874, COSV60014949; called by muse, mutect2, varscan2
- GRPR | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.247); catalogued as COSV66668953; called by muse, mutect2, varscan2
- HCK | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.018); catalogued as COSV52940379, COSV52946376; called by muse, mutect2, varscan2
- HEATR9 | c.155T>G p.F52C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs997603003; called by muse, mutect2, varscan2
- HERC1 | c.8407G>A p.E2803K | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as COSV101496381; called by muse, mutect2, varscan2
- HMCN1 | c.13954T>A p.W4652R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54879080; called by muse, mutect2, varscan2
- KALRN | c.257+1G>T p.X86_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53753739; called by muse, mutect2, varscan2
- KCNB2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73048998, COSV73050348; called by muse, mutect2, varscan2
- KCNH4 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs141418259; called by muse, mutect2, varscan2
- KIAA0825 | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 268/460 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV56948004; called by muse, varscan2
- KPNA3 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV55503333; called by muse, mutect2, varscan2
- KPRP | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 126/300 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs201616422, COSV64221035; called by muse, mutect2, varscan2
- LHCGR | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV54298238; called by muse, mutect2
- LRP2 | c.12156C>G p.S4052R | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV99786833; called by muse, mutect2, varscan2
- MACROH2A1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 132/485 reads (27%) | catalogued as COSV100427549; called by muse, mutect2, varscan2
- MAP4K4 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV56325472; called by muse, mutect2, varscan2
- MDC1 | c.4168C>T p.R1390W | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs144566920; called by muse, mutect2, varscan2
- MFSD8 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 112/195 reads (57%) | catalogued as COSV56550449; called by muse, mutect2, varscan2
- MLH1 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV99212344; called by muse, mutect2, varscan2
- MPI | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV60396338; called by muse, mutect2, varscan2
- MYOM2 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.871); catalogued as rs562106463, COSV50702591; called by muse, mutect2, varscan2
- NAP1L3 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59073814; called by muse, mutect2, varscan2
- NBEA | c.7235G>A p.R2412Q | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1188006894, COSV59761880; called by muse, mutect2, varscan2
- NLRP2 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 134/233 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs142821233; called by muse, mutect2, varscan2
- NPAS4 | c.869G>C p.G290A | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV100214836; called by muse, mutect2, varscan2
- NRG1 | c.1113C>G p.I371M (on ENST00000405005 / NM_013964.5; = p.I376M on NM_013956.5) | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.749); catalogued as COSV55149045, COSV55149103; called by muse, mutect2
- NRG3 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV64545740; called by muse, mutect2
- NRROS | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs368543951; called by muse, mutect2, varscan2
- OR1L6 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 180/265 reads (68%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs367605682; called by muse, varscan2
- OR2A14 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs201108825; called by muse, mutect2, varscan2
- OR2T8 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100178100; called by muse, mutect2, varscan2
- OR5P2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61489955; called by muse, mutect2
- PAPPA | c.464T>G p.V155G | Missense Mutation (SNP) | VAF 123/197 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100073074; called by muse, mutect2, varscan2
- PIAS3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 112/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100566736; called by muse, mutect2, varscan2
- PIGN | c.2741T>G p.L914R | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV62947858; called by muse, mutect2, varscan2
- PLG | c.509A>T p.E170V | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as COSV51980801, COSV51985473; called by muse, mutect2, varscan2
- PLPPR4 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs754693317, COSV64564446; called by muse, mutect2, varscan2
- PLXNB2 | c.5059C>T p.R1687W | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293031275, COSV63780183; called by muse, mutect2, varscan2
- PLXNB2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs774126870, COSV63780185; called by muse, mutect2, varscan2
- PPP1R26 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1396694655, COSV63354757; called by muse, mutect2, varscan2
- PRKAG1 | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100304796, COSV60291580; called by muse, mutect2, varscan2
- PRSS1 | c.237A>C p.E79D | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61190610; called by muse, mutect2, varscan2
- PSMB2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557445262, COSV100951577; called by muse, varscan2
- PTPRR | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99316518; called by muse, mutect2, varscan2
- RBBP6 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as rs371006887; called by muse, mutect2
- RICTOR | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 106/420 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.135); catalogued as COSV57117379; called by muse, mutect2, varscan2
- RIOX1 | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs751393987, COSV100407913; called by muse, mutect2, varscan2
- RNASE10 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60517408; called by muse, mutect2, varscan2
- RNF7 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 109/493 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV56421730; called by muse, mutect2, varscan2
- RNF7 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 110/495 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV56421738; called by muse, mutect2, varscan2
- RXFP1 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV100313579; called by muse, mutect2
- SCN5A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs762012668, COSV61116418; ClinVar: uncertain significance; called by muse, mutect2
- SHC3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs771029388, COSV65436887, COSV65439537; called by muse, mutect2, varscan2
- SLC44A5 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100902887, COSV63758646; called by muse, mutect2, varscan2
- SLC4A7 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as rs1288946567, COSV55396974; called by muse, mutect2, varscan2
- SLU7 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51786583; called by muse, mutect2, varscan2
- SMAD3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs762012589, CM158151, COSV100528797; called by muse, mutect2, varscan2
- SP100 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV60841986; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 150/333 reads (45%) | PolyPhen benign (0.329); catalogued as rs114284775, COSV60321424; called by muse, mutect2, varscan2
- SYNM | c.1601A>T p.E534V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60367605; called by muse, mutect2, varscan2
- TDRD6 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100287205; called by muse, mutect2, varscan2
- TEKT5 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768273976, COSV51586722, COSV99295769; called by muse, mutect2, varscan2
- TENM2 | c.895G>A p.V299I (on ENST00000518659 / NM_001122679.2; = p.V108I on NM_001080428.3) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1209382397, COSV101319482, COSV69123156; called by muse, mutect2, varscan2
- TMEM100 | c.152T>A p.L51H | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV70117902; called by muse, mutect2, varscan2
- TMEM106C | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV56742197; called by muse, mutect2, varscan2
- TRIM17 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1367521517, COSV99694549; called by muse, mutect2, varscan2
- TRPC7 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs1370899715, COSV61457865; called by muse, mutect2, varscan2
- TSHZ3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs923574447, COSV53665122; called by muse, mutect2, varscan2
- TTN | c.28913G>A p.R9638Q (on ENST00000591111; = p.R8711Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/192 reads (24%) | PolyPhen benign (0.019); catalogued as rs182332374; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBA4A | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as rs769120095, COSV99944635; called by muse, mutect2, varscan2
- UBE2V2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV72878757; called by muse, mutect2, varscan2
- VAV1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58378980; called by muse, mutect2, varscan2
- VPS53 | c.662A>T p.E221V (on ENST00000571805 / NM_001366253.2; = p.E192V on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99345500; called by muse, mutect2, varscan2
- VWA8 | c.5285G>T p.G1762V | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99061952; called by muse, mutect2
- WDFY3 | c.9329C>T p.S3110F | Missense Mutation (SNP) | VAF 224/382 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55693949; called by muse, varscan2
- WDR6 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58244015; called by muse, mutect2, varscan2
- XAF1 | c.564A>T p.E188D | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs778052611, COSV60971323; called by muse, mutect2, varscan2
- XYLB | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV52911630; called by muse, mutect2, varscan2
- ZAP70 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV53852372; called by muse, mutect2, varscan2
- ZNF345 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as rs1305166527, COSV59322726; called by muse, mutect2, varscan2
- AGPAT1 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2
- ENTPD1 | c.500_515del p.R167Kfs*27 | Frame Shift Del (DEL) | VAF 18/168 reads (11%) | called by mutect2, pindel
- GFRA1 | c.1208_1214del p.L403Pfs*27 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- MMP28 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- SLAMF7 | c.720_721del p.F241Cfs*19 | Frame Shift Del (DEL) | VAF 97/536 reads (18%) | called by pindel, varscan2
- TPSD1 | c.364_374del p.I122Rfs*48 | Frame Shift Del (DEL) | VAF 82/1208 reads (7%) | called by mutect2, pindel
- XIRP2 | c.4335_4348del p.E1445Dfs*2 (on ENST00000628543; = p.E1620Dfs*2 on NM_152381.6) | Frame Shift Del (DEL) | VAF 38/145 reads (26%) | called by mutect2, pindel, varscan2
- ACE | c.525C>T p.I175= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs780935754, COSV52016841, COSV52026789; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1770C>T p.N590= | Silent (SNP) | VAF 81/329 reads (25%) | catalogued as COSV54996683; called by muse, mutect2, varscan2
- AK9 | c.78G>A p.L26= | Silent (SNP) | VAF 50/211 reads (24%) | catalogued as COSV53419786; called by muse, mutect2, varscan2
- ANKS3 | c.1914G>C p.V638= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as COSV100422958; called by muse, mutect2, varscan2
- ANKS6 | c.696C>T p.A232= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs775805698, COSV62048982; called by muse, mutect2, varscan2
- C1GALT1 | c.651A>G p.K217= | Silent (SNP) | VAF 38/348 reads (11%) | catalogued as COSV56178758; called by muse, mutect2, varscan2
- CCHCR1 | c.1521G>A p.Q507= | Silent (SNP) | VAF 91/189 reads (48%) | catalogued as COSV66182872; called by muse, mutect2, varscan2
- CCNB3 | c.2775C>A p.V925= | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as rs781936119, COSV52073497, COSV99328573; called by muse, mutect2, varscan2
- CDH2 | c.1038G>A p.T346= | Silent (SNP) | VAF 63/209 reads (30%) | catalogued as rs140193518; called by muse, mutect2, varscan2
- CMTR1 | c.1383C>T p.F461= | Silent (SNP) | VAF 66/290 reads (23%) | catalogued as rs542774031, COSV65089289; called by muse, mutect2, varscan2
- CRMP1 | c.1410G>A p.P470= | Silent (SNP) | VAF 42/225 reads (19%) | catalogued as rs370052265, COSV100271466; called by muse, mutect2, varscan2
- DAAM2 | c.1569A>C p.P523= | Silent (SNP) | VAF 84/176 reads (48%) | catalogued as COSV99224809; called by muse, mutect2, varscan2
- DNTT | c.300G>A p.E100= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV64522644; called by muse, mutect2
- FAT4 | c.11001T>C p.T3667= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV58672461; called by muse, mutect2, varscan2
- FNDC11 | c.687C>T p.F229= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs150942473; called by muse, mutect2, varscan2
- GPR17 | c.852C>T p.S284= | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as rs1167205650, COSV55754037, COSV99760667; called by muse, mutect2, varscan2
- HFM1 | c.3003G>A p.T1001= | Silent (SNP) | VAF 280/510 reads (55%) | catalogued as rs1333512848, COSV54021433; called by muse, varscan2
- HSF2 | c.603T>G p.L201= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV63773423; called by muse, mutect2
- HTR2A | c.501C>T p.C167= | Silent (SNP) | VAF 163/343 reads (48%) | catalogued as rs776463683, COSV66326609; called by muse, mutect2, varscan2
- IGLV8-61 | c.93G>A p.E31= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs556491223, COSV66503038; called by muse, mutect2, varscan2
- KANSL1 | c.2901G>A p.Q967= (on ENST00000574590 / NM_001193465.2; = p.Q968= on NM_015443.4) | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- MACC1 | c.1878A>T p.S626= | Silent (SNP) | VAF 42/345 reads (12%) | catalogued as COSV60540939; called by muse, mutect2, varscan2
- MDGA1 | c.993C>T p.N331= | Silent (SNP) | VAF 84/197 reads (43%) | catalogued as rs566670245, COSV51791984; called by muse, mutect2, varscan2
- MPDZ | c.4906C>A p.R1636= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV100056263; called by muse, mutect2, varscan2
- NAV3 | c.5844C>A p.T1948= (on ENST00000397909 / NM_001024383.2; = p.T1926= on NM_014903.6) | Silent (SNP) | VAF 64/224 reads (29%) | catalogued as COSV57063232; called by muse, mutect2, varscan2
- NEXN | c.1881C>T p.D627= | Silent (SNP) | VAF 50/275 reads (18%) | catalogued as COSV99627987; called by muse, mutect2, varscan2
- NFATC2 | c.1134G>A p.P378= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV65353305; called by muse, mutect2, varscan2
- NPAP1 | c.618G>T p.G206= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV61504657; called by muse, mutect2, varscan2
- NYAP2 | c.1137G>A p.S379= | Silent (SNP) | VAF 69/270 reads (26%) | catalogued as rs762429077, COSV56009570; called by mutect2, varscan2
- OOSP2 | c.339C>T p.S113= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV53928224; called by muse, mutect2, varscan2
- OPTN | c.1518C>T p.F506= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs776931295, COSV53809780; called by muse, mutect2, varscan2
- PAX1 | c.702C>T p.Y234= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV68271154; called by muse, mutect2
- PCDHB8 | c.1401C>T p.P467= | Silent (SNP) | VAF 62/524 reads (12%) | catalogued as COSV99176079; called by muse, mutect2, varscan2
- PRRC2C | c.7578A>G p.E2526= (on ENST00000367742; = p.E2524= on NM_015172.4) | Silent (SNP) | VAF 72/323 reads (22%) | catalogued as COSV58901431; called by muse, mutect2, varscan2
- PSEN2 | c.216G>A p.P72= | Silent (SNP) | VAF 48/177 reads (27%) | catalogued as COSV60914985; called by muse, mutect2, varscan2
- RALB | c.276G>T p.V92= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as COSV55602071; called by muse, mutect2, varscan2
- RAP1GAP2 | c.174G>A p.E58= | Silent (SNP) | VAF 154/272 reads (57%) | catalogued as COSV54571998, COSV54572457; called by muse, mutect2, varscan2
- RYR1 | c.3780C>T p.D1260= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as COSV62089575; called by muse, mutect2, varscan2
- RYR3 | c.13179G>C p.G4393= (on ENST00000389232; = p.G4394= on NM_001036.6) | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV66778781; called by muse, mutect2, varscan2
- SBNO1 | c.4181G>A p.*1394= (on ENST00000420886; = p.*1393= on NM_018183.5) | Silent (SNP) | VAF 102/369 reads (28%) | catalogued as COSV57339150; called by muse, mutect2, varscan2
- SEMA3D | c.435G>T p.V145= | Silent (SNP) | VAF 31/411 reads (8%) | catalogued as COSV99406024; called by muse, mutect2
- SLC32A1 | c.1206C>T p.V402= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as COSV54145734; called by muse, mutect2, varscan2
- SLC6A20 | c.1620C>T p.D540= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs758616442, COSV62070202; called by muse, mutect2, varscan2
- STX18 | c.984C>T p.L328= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV60371724; called by muse, mutect2, varscan2
- TEKT5 | c.327G>T p.R109= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV51591856; called by muse, mutect2, varscan2
- TIMM44 | c.462G>A p.K154= | Silent (SNP) | VAF 118/196 reads (60%) | catalogued as COSV54490125; called by muse, mutect2, varscan2
- TMEM100 | c.153C>A p.L51= | Silent (SNP) | VAF 63/169 reads (37%) | catalogued as COSV101448210; called by muse, mutect2, varscan2
- TNXB | c.10803G>A p.P3601= (on ENST00000647633; = p.P3354= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/192 reads (42%) | catalogued as rs777306398, COSV100926873, COSV64482793; called by muse, mutect2, varscan2
- TRIM58 | c.42G>A p.A14= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV100824921; called by muse, mutect2
- VASH2 | c.246C>T p.G82= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV55116926; called by muse, mutect2, varscan2
- CDKL1 | chr14:50397264 del TGTC | 5'Flank (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
